Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5705, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5705-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of left renal cancer.

PRE-OP DIAGNOSIS: Left renal cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic left radical nephrectomy.

FINAL DIAGNOSIS:

KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA (4.5 CM), CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR 2 OF 4.
B. TUMOR DOES NOT EXTEND BEYOND RENAL CAPSULE.
C. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
E. TNM PATHOLOGIC STAGE = p T1 NX MX.
F. NON NEOPLASTIC KIDNEY SHOW S CHRONIC INTERSTITIAL INFLAMMATION.

KIDNEY/RENAL PELVIS/URETER TUMORS

- A. Side: 2 1. Right 2. Left
B. Location: 2
1. Kidney (parenchyma - cortex/medulla) 3. Ureter
2. Kidney (pelvis) 4. Kidney and ureter
C. Procedure: 3
1. Partial nephrectomy 4. Ureterectomy
2. Simple nephrectomy 5. Other
3. Radical nephrectomy
D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 4.5 cm
E. Type of malignant neoplasm: 1
1. Renal cell carcinoma, clear cell type 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
(includes non-papillary granular cell RCC)
2. Renal cell carcinoma, chromophil cell type 12. Urothelial carcinoma, mixed
(papillary RCC, no clear cell component)
3. Renal cell carcinoma, chromophobe cell type 13. Juxtaglomerular cell tumor
4. Renal cell carcinoma, oncocytic 14. Wilms' tumor
5. Renal cell carcinoma, sarcomatoid 15. Rhabdoid tumor
6. Collecting duct carcinoma 16. Clear cell sarcoma
7. Urothelial carcinoma, TCCa 17. Congenital mesoblastic nephroma
(non-invasive)
8. Urothelial carcinoma, TCCa 18. Sarcoma (non-clear cell)
(invasive ± in-situ)
9. Urothelial carcinoma, squamous carcinoma 19. Lymphoma/leukemia
10. Urothelial carcinoma, adenocarcinoma 20. Other
F. Histologic grade
F1. Fuhrman grade (for RCC; grades 1-4): 2
F2. Ash grade (grade 1-4): #
F3. WHO grade (grade 1-3): # (for TCCa)
F4. 1998 WHO/ISUP Classification: #
1. LMP 2. LG 3. HG
F5. Other malignant neoplasms (grades 1-3): #
G. Non-neoplastic and other conditions: # / # / # / #
1. Glomerulopathy
2. Interstitial nephritis
3. Pyelonephritis
4. Nephrolithiasis
5. Papillary necrosis
6. Chronic parenchymal disease
7. Other
H. Margins of resection: 2 1. Positive 2. Negative
I. Mitotic activity: 1 per 10 high power fields
J. Angiolymphatic invasion
J1. Macroscopic (e.g., renal vein thrombus): 2 1. Positive 2. Negative
J2. Microscopic: 2 1. Positive 2. Negative
K. Number of positive lymph nodes: #
L. Total number of lymph nodes examined: 0
M. Extracapsular spread of lymph node metastases: #
1. Yes 2. No
N. Adrenal gland:
N1. Present 2 1. Yes 2. No
N2. Involvement by renal neoplasm: 3 1. Yes 2. No 3. Not Applicable
N3. Other adrenal pathology: 3 1. Yes 2. No 3. Not applicable
O. TNM stage: T 1 N X M X

Source: NCI Genomic Data Commons file ca2b3cd8-fe65-48a8-b95b-ab36fc2fb536 (TCGA-B0-5705.E29A3387-2212-4514-823E-5F692E1E6799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).